Somatic mutation profile of tumor specimen TCGA-CQ-6223-01A (aliquot TCGA-CQ-6223-01A-11D-1912-08) from TCGA case TCGA-CQ-6223, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.2 years (25,266 days).
Specimen TCGA-CQ-6223-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb50a673-141c-4c3b-bcb0-e091e5c6eff2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6223-10A (Blood Derived Normal), aliquot TCGA-CQ-6223-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c805a01-cca9-4fa5-a0c1-6bccc487ffd8

The open-access MAF lists 92 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 19, Nonsense Mutation 4, Intron 3, Splice Site 2, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRF1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs28933973, CM992951, COSV64615781; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121917923, CM076506, CM1311645, COSV100322459; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs759324902, COSV56644177; called by muse, mutect2, varscan2
- ADAM2 | c.1312-2A>G p.X438_splice | Splice Site (SNP) | VAF 32/96 reads (33%) | catalogued as COSV99698000; called by muse, mutect2, varscan2
- AL662899.2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as rs1176586804, COSV101021787; called by muse, mutect2, varscan2
- ALG6 | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99673573; called by muse, mutect2, varscan2
- AP5M1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841393; called by muse, mutect2, varscan2
- BCO1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs747676129, COSV50729947; called by muse, mutect2, varscan2
- CACNA1E | c.6568G>A p.E2190K (on ENST00000367573 / NM_001205293.3; = p.E2147K on NM_000721.4) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs751185780, COSV62401289; called by muse, mutect2, varscan2
- CBL | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as rs373587039; called by muse, mutect2, varscan2
- CDHR5 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99449357; called by muse, mutect2, varscan2
- CEACAM5 | c.1778C>A p.P593Q | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55752454, COSV99704203; called by muse, mutect2, varscan2
- CEP170 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV100317998; called by muse, mutect2, varscan2
- CHD2 | c.5014G>T p.D1672Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV101246119; called by muse, mutect2, varscan2
- COL6A6 | c.3050A>C p.K1017T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100651035; called by muse, mutect2, varscan2
- CPT1A | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV99681662; called by muse, mutect2, varscan2
- CPVL | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038595717, COSV99606516; called by muse, mutect2, varscan2
- CSNK2A2 | c.513G>A p.K171= | Splice Region (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99345510; called by muse, mutect2, varscan2
- DRGX | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV100938403; called by muse, varscan2
- DZANK1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs542484500, COSV52747058; called by mutect2, varscan2
- EPHA5 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs780101856, COSV99901708; called by muse, mutect2, varscan2
- FAT1 | c.3340C>T p.Q1114* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV71672622; called by muse, mutect2
- FGF13 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs1264974671, COSV59542497; called by muse, mutect2, varscan2
- FGFR1 | c.626G>A p.R209H (on ENST00000447712 / NM_023110.3; = p.R207H on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM114759, COSV58348919; called by muse, mutect2, varscan2
- FN1 | c.5689A>C p.I1897L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.029); catalogued as COSV100118471; called by muse, mutect2, varscan2
- GALNT10 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs147745456; called by muse, mutect2, varscan2
- GLI4 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60682835; called by muse, mutect2
- GRHL1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.191); catalogued as COSV100258247; called by muse, mutect2, varscan2
- HERC2 | c.3661G>A p.D1221N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55309799; called by muse, mutect2, varscan2
- KLHL1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV64766779, COSV64775805; called by muse, mutect2, varscan2
- KRT33B | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs148300082; called by muse, mutect2, varscan2
- L1TD1 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1330956137, COSV100776636; called by muse, mutect2, varscan2
- MAMDC4 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs758715335, COSV100440708; called by muse, mutect2, varscan2
- MFSD13A | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99488095; called by muse, mutect2, varscan2
- MXRA5 | c.7856G>T p.R2619L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99479651; called by muse, mutect2, varscan2
- MYBPC2 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746502452, COSV63099979; called by muse, mutect2
- OBSCN | c.4228C>T p.Q1410* | Nonsense Mutation (SNP) | VAF 43/141 reads (30%) | catalogued as COSV99485198; called by muse, mutect2, varscan2
- OR5H2 | c.862C>G p.P288A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100788849; called by muse, mutect2, varscan2
- OR6T1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.173); catalogued as COSV58307424; called by muse, mutect2, varscan2
- PATJ | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201550049, COSV57159083; called by muse, mutect2, varscan2
- PLA2G4F | c.1780+1G>T p.X594_splice | Splice Site (SNP) | VAF 19/132 reads (14%) | catalogued as COSV101215438; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2123_2124del p.I708Sfs*75 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs1196797384; called by mutect2, pindel, varscan2
- PROX1 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs201989339, COSV99800337; called by muse, mutect2, varscan2
- RAB3C | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99278935; called by muse, mutect2, varscan2
- RAC1 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100641092; called by muse, mutect2, varscan2
- RASGRF1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1199183242, COSV69177307; called by muse, mutect2, varscan2
- RBBP8 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59091190, COSV59093279; called by muse, mutect2, varscan2
- RREB1 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100619923; called by muse, mutect2, varscan2
- SCAF11 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV101014725; called by muse, mutect2, varscan2
- SCN7A | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs369751581, COSV101313377, COSV69275976; called by muse, mutect2, varscan2
- SDK2 | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs751928180, COSV101167613; called by muse, mutect2, varscan2
- SLC25A14 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 36/57 reads (63%) | catalogued as COSV54420391; called by muse, mutect2, varscan2
- SLC5A6 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs188933728, COSV100143643; called by muse, mutect2, varscan2
- SLF1 | c.2618T>C p.V873A | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99476409; called by muse, mutect2, varscan2
- SMAD5 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101548151; called by muse, mutect2, varscan2
- SPATA2 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV56866167, COSV99193005; called by muse, mutect2, varscan2
- SPTBN5 | c.8087C>T p.A2696V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs372953121; called by muse, mutect2, varscan2
- ST18 | c.2093A>T p.K698M | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52509029; called by muse, mutect2, varscan2
- TMEFF2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1485161242, COSV55830397; called by muse, mutect2, varscan2
- TNK2 | c.2774C>G p.T925S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100361790; called by muse, varscan2
- TPPP2 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs979234395, COSV100409682; called by muse, mutect2, varscan2
- TRIM46 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.251); catalogued as rs771021407, COSV100584196, COSV58113063; called by muse, mutect2, varscan2
- TRIP11 | c.3484T>G p.L1162V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50914472; called by muse, mutect2, varscan2
- TTN | c.47106C>G p.D15702E (on ENST00000591111; = p.D8278E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | PolyPhen benign (0.355); catalogued as COSV100633472; called by muse, varscan2
- UNC5C | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs150089453, COSV71659572; called by muse, mutect2, varscan2
- USP29 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99572567; called by muse, mutect2, varscan2
- ZNF829 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.317); catalogued as COSV101199742; called by muse, mutect2, varscan2
- ZNF835 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as rs1043552123, COSV73379133; called by muse, mutect2, varscan2
- SERPINE1 | c.772dup p.M258Nfs*8 | Frame Shift Ins (INS) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- AC008397.2 | c.1287C>T p.D429= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs762091835, COSV99442368; called by muse, mutect2, varscan2
- ACACB | c.2568G>A p.G856= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs1290219062, COSV100623350; called by muse, mutect2, varscan2
- AEN | c.204C>T p.F68= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs780933013, COSV100237657; called by muse, mutect2, varscan2
- AL592490.1 | c.2001C>T p.D667= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs535309463, COSV69427096; called by muse, mutect2, varscan2
- ASB8 | c.690G>A p.V230= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100402796; called by muse, mutect2, varscan2
- COL16A1 | c.1644C>A p.I548= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV99595641; called by muse, mutect2, varscan2
- COPG1 | c.2289C>T p.H763= | Silent (SNP) | VAF 108/202 reads (53%) | catalogued as COSV100136002; called by muse, mutect2, varscan2
- DNMT3A | c.1083G>A p.K361= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99264965; called by muse, mutect2, varscan2
- DOCK2 | c.4014C>A p.P1338= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99915995; called by muse, mutect2, varscan2
- FREM2 | c.3540C>T p.P1180= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as COSV99751352; called by muse, mutect2, varscan2
- KMT2B | c.3891T>C p.C1297= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99720808; called by muse, mutect2
- NLRP3 | c.1698C>T p.F566= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs750708367, CM141590, COSV60226447; called by muse, mutect2, varscan2
- PCDHGA9 | c.1722T>C p.G574= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as COSV99548486; called by muse, mutect2, varscan2
- POLR1H | c.135C>A p.I45= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100198512; called by muse, mutect2, varscan2
- PPP1R13B | c.2106C>G p.P702= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV99162982; called by muse, mutect2, varscan2
- SH3PXD2B | c.357G>T p.L119= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100288612; called by muse, mutect2, varscan2
- SYT10 | c.978A>G p.R326= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99952066; called by muse, mutect2, varscan2
- VWA5A | c.882C>T p.S294= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100795768; called by muse, mutect2, varscan2
- ZC3H18 | c.306C>T p.D102= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1055524638, COSV99964522; called by muse, mutect2, varscan2
- MFSD4B | c.27+2670C>A | Intron (SNP) | VAF 45/143 reads (31%) | catalogued as COSV100920617, COSV64349215; called by muse, mutect2, varscan2
- RUFY2 | c.1310+776A>G | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as rs1463337330, COSV99769513; called by muse, mutect2, varscan2
- STEAP3 | c.-77+7130G>A | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as rs753931702, COSV100713512; called by muse, mutect2, varscan2
